Somatic mutation profile of tumor specimen TCGA-2G-AAGS-01A (aliquot TCGA-2G-AAGS-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 39.2 years (14,312 days).
Specimen TCGA-2G-AAGS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd3a590c-e2f4-4294-8647-b30c66171dcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGS-10A (Blood Derived Normal), aliquot TCGA-2G-AAGS-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/733b9bea-a40c-4740-8b5b-d5e57abdfedc

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 1, In Frame Del 1, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKG | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs560924252; called by muse, mutect2, varscan2
- PHLDA3 | c.239del p.G80Afs*21 | Frame Shift Del (DEL) | VAF 61/237 reads (26%) | catalogued as rs1415703791; called by mutect2, pindel, varscan2
- RGS12 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1204383004, COSV60901999; called by muse, mutect2, varscan2
- CIC | c.2902C>G p.P968A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- EBF3 | c.610A>C p.N204H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- ERO1B | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FKBP14 | c.393_395del p.L132del | In Frame Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- MED1 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SSC5D | c.2017T>C p.S673P | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL14A1 | c.1290T>C p.A430= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- PRAME | c.22-1731C>G | Intron (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.-132G>A | 5'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
